TCGA case TCGA-39-5039 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ffb83f21-06d9-4e52-a2d0-e85c13f4037f

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 76 years; Vital status: Dead; Days to death: 544 days (1.5 years).

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 76.1 years (27,781 days); Year of diagnosis: 2008; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the prostate gland (histology not recorded by GDC).
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Hormone Therapy; Treatment anatomic sites: Body, total.

Follow-up (1 entry)
- Days to follow up: 544 days (1.5 years); Disease response: Tumor Free.

Molecular and laboratory tests
- KRAS mutation, nos: Negative.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 64; Tobacco smoking onset year: 1949; Tobacco smoking quit year: 1983.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-39-5039-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 1.2; Shortest dimension: 0.1.
  Slide TCGA-39-5039-01A-01-TS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 30.
  Slide TCGA-39-5039-01A-01-BS1: Section location: Bottom; Percent tumor cells: 55; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 40.
- Sample TCGA-39-5039-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-39-5039-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 1.4; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Upper; Location lung parenchyma: Central Lung; KRAS mutation found: No; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; New tumor event surgery: No; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No; Treatment outcome at TCGA followup: Complete Remission/Response.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form, Drug treatment, Administered drug: Pharmaceutical therapy drug name: Agents unknown - pt received 6 months of hormonal therapy for prostate ca.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No.

GDC annotations on this case (curator notes; quoted as recorded):
- History of acceptable prior treatment related to a prior/other malignancy: Prior malignancy prostate cancer, treated with hormone therapy and locoregional radiation.
- Prior malignancy: Subject has Hx of prior malignancy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 544 days; disease-specific survival: no event (censored), 544 days; disease-free interval: no event (censored), 544 days; progression-free interval: no event (censored), 544 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-39-5039-01A-01D-1439-01): tumor purity 0.28, ploidy 1.86, whole-genome doublings 0.
